Somatic mutation profile of tumor specimen C3N-04092-03 (aliquot CPT0285440006) from CPTAC case C3N-04092, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.5 years (22,821 days).
Specimen C3N-04092-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef381a33-7520-40f8-a057-0d2b7fc5092e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04092-31 (Blood Derived Normal), aliquot CPT0285450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c1f010e-fc68-40c9-9c7b-4d99630e29aa

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Intron 5, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 3, 5'Flank 2, In Frame Ins 1, Translation Start Site 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 52/74 reads (70%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- ADAMTS12 | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745489312, COSV61254566, COSV61256573, COSV61285243; called by muse, mutect2, varscan2
- CARD6 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99621280; called by muse, mutect2, varscan2
- CHD5 | c.5215C>T p.R1739C | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs776805670; called by muse, mutect2, varscan2
- COL22A1 | c.2592+1G>A p.X864_splice | Splice Site (SNP) | VAF 190/384 reads (49%) | catalogued as rs201713235; called by muse, mutect2, varscan2
- COL7A1 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 280/487 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs748471791, COSV100097538; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CYSLTR1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773734601, COSV64821437; called by muse, mutect2, varscan2
- EPPK1 | c.6646G>A p.V2216I | Missense Mutation (SNP) | VAF 232/369 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs1307338641, COSV73261585; called by muse, mutect2, varscan2
- GPAT3 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs367948973; called by muse, mutect2, varscan2
- IGFBP2 | c.64_65insCGCTGC p.L21_L22insPL | In Frame Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs1461501999; called by mutect2, pindel
- MUC12 | c.14413C>T p.P4805S (on ENST00000379442; = p.P4662S on NM_001164462.1) | Missense Mutation (SNP) | VAF 184/823 reads (22%) | SIFT deleterious, low confidence (0.02); catalogued as rs748976700; called by muse, mutect2
- MYCT1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs17852097, COSV65891766; called by muse, mutect2, varscan2
- MYH4 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs185822918; called by muse, mutect2, varscan2
- OR2A1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 44/330 reads (13%) | catalogued as rs779625135; called by mutect2, varscan2
- PCDHA2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 375/887 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV65367194; called by muse, mutect2, varscan2
- PPFIBP1 | c.1988C>T p.S663L (on ENST00000318304 / NM_177444.3; = p.S657L on NM_003622.4) | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs564190529, COSV57287128; called by muse, mutect2, varscan2
- PRKACG | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 141/342 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55245418; called by muse, mutect2, varscan2
- PRKAR2B | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.159); catalogued as COSV99708580; called by muse, mutect2, varscan2
- RPS6KA2 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs1470862955, COSV99690452; called by muse, mutect2, varscan2
- SHISA2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as rs372812470, COSV60110068; called by muse, mutect2, varscan2
- SLC7A9 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 210/720 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs373579480, COSV50084907; called by muse, mutect2, varscan2
- SSC5D | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as rs1401311572; called by muse, mutect2, varscan2
- TERT | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs778051907, COSV57197668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOPORS | c.1949A>G p.D650G | Missense Mutation (SNP) | VAF 152/392 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV62116583; called by muse, mutect2, varscan2
- ZNF804A | c.2402C>T p.T801I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100167896, COSV100170172; called by muse, mutect2
- CCN4 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 121/468 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEL | c.76-2A>T p.X26_splice (on ENST00000673714; = p.X23_splice on NM_001807.6) | Splice Site (SNP) | VAF 139/360 reads (39%) | called by muse, mutect2, varscan2
- CFAP206 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 131/346 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CSMD3 | c.5861G>A p.G1954E (on ENST00000297405 / NM_001363185.1; = p.G1850E on NM_052900.3) | Missense Mutation (SNP) | VAF 115/499 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP4A22 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- EPHA2 | c.1514T>G p.V505G | Missense Mutation (SNP) | VAF 147/345 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EPHA7 | c.2362G>T p.E788* | Nonsense Mutation (SNP) | VAF 84/200 reads (42%) | called by muse, mutect2, varscan2
- FGGY | c.626_630del p.M209Rfs*9 | Frame Shift Del (DEL) | VAF 43/190 reads (23%) | called by mutect2, pindel, varscan2
- GABRG3 | c.745T>A p.L249M | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GCSAM | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- HAL | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 163/476 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IL18R1 | c.59-2A>C p.X20_splice | Splice Site (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- JPH2 | c.1359del p.D454Tfs*54 | Frame Shift Del (DEL) | VAF 133/502 reads (26%) | called by mutect2, pindel, varscan2
- LEO1 | c.1674_1675del p.K559Tfs*14 | Frame Shift Del (DEL) | VAF 72/290 reads (25%) | called by pindel, varscan2
- MARS2 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 47/510 reads (9%) | called by muse, mutect2
- MYO6 | c.3065A>C p.E1022A | Missense Mutation (SNP) | VAF 143/401 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PNISR | c.1030_1031del p.E344Nfs*8 | Frame Shift Del (DEL) | VAF 49/135 reads (36%) | called by mutect2, pindel, varscan2
- POM121L2 | c.679A>T p.S227C | Missense Mutation (SNP) | VAF 151/388 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RLBP1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA5A | c.1672A>G p.S558G | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31D1 | c.1473C>A p.C491* | Nonsense Mutation (SNP) | VAF 173/447 reads (39%) | called by muse, mutect2, varscan2
- TESPA1 | c.207A>G p.G69= | Splice Region (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- TUBB4B | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 299/900 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VRK2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 154/234 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZFC3H1 | c.3029C>T p.P1010L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BEND3 | c.1905C>T p.F635= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs1417714071, COSV100944718; called by muse, mutect2, varscan2
- BMX | c.1500C>T p.Y500= | Silent (SNP) | VAF 151/187 reads (81%) | called by muse, mutect2, varscan2
- CASD1 | c.357A>G p.E119= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs1186993701; called by muse, mutect2, varscan2
- FAH | c.1161G>A p.G387= | Silent (SNP) | VAF 91/241 reads (38%) | called by muse, mutect2, varscan2
- FAM131B | c.48G>A p.S16= | Silent (SNP) | VAF 98/343 reads (29%) | catalogued as rs752893250; called by muse, mutect2, varscan2
- KIAA1109 | c.5157T>G p.G1719= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2
- LBR | c.291T>G p.S97= | Silent (SNP) | VAF 150/290 reads (52%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.195T>A p.P65= | Silent (SNP) | VAF 100/256 reads (39%) | called by muse, mutect2, varscan2
- MOS | c.982A>C p.R328= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- OR51A4 | c.603C>G p.G201= | Silent (SNP) | VAF 128/396 reads (32%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.990C>T p.H330= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs781648469; called by muse, mutect2, varscan2
- TRPC7 | c.723C>T p.T241= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs748248116, COSV61458318; called by muse, mutect2, varscan2
- ZIC4 | c.342C>T p.G114= | Silent (SNP) | VAF 127/455 reads (28%) | catalogued as COSV101267960; called by muse, mutect2, varscan2
- AC011503.1 | n.467+8603A>C | Intron (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3235A>G | Intron (SNP) | VAF 116/184 reads (63%) | called by muse, mutect2, varscan2
- KCNQ5 | c.616+1022C>T | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as rs145744729, COSV59660159; called by muse, mutect2
- MEIS1 | c.743-3108C>G | Intron (SNP) | VAF 15/170 reads (9%) | catalogued as rs1450746524; called by muse, mutect2
- MIR5195 | chr14:106851137 G>A | 5'Flank (SNP) | VAF 62/171 reads (36%) | catalogued as rs551872232; called by muse, varscan2
- OBSCN | c.5138-353C>G | Intron (SNP) | VAF 259/608 reads (43%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568125 C>T | 5'Flank (SNP) | VAF 37/55 reads (67%) | catalogued as rs773000829, COSV58216577; called by muse, mutect2, varscan2
- UGT2B27P | n.1613G>A | RNA (SNP) | VAF 58/138 reads (42%) | catalogued as rs796516317; called by muse, varscan2
